Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8QF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8QF-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

"Biopsy of the cervix":

- Invasive squamous cell carcinoma, histological grade 2.

100-0-3
Carcinoma, squamous cell NOS
8070/3
Site Cervix NOS
C53.9
9/26/14

Histology Discrepancy		✓
Qual/Syn. Bronchus Primary Notes		✓

Source: NCI Genomic Data Commons file c993eb5f-3a01-4c16-bc76-45a78c7871d9 (TCGA-VS-A8QF.9E014162-B8BD-4DDD-9E8C-A1D18A6A8A7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).